Somatic mutation profile of tumor specimen TCGA-XS-A8TJ-01A (aliquot TCGA-XS-A8TJ-01A-11D-A36J-09) from TCGA case TCGA-XS-A8TJ, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, large cell, nonkeratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IB1; Tumor grade: G2; Age at diagnosis: 41.9 years (15,298 days).
Specimen TCGA-XS-A8TJ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 12ced3ed-0f0d-4e11-a9b7-8b32b7e162d5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-XS-A8TJ-10A (Blood Derived Normal), aliquot TCGA-XS-A8TJ-10A-01D-A36M-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/be11a03f-5cbe-4149-95c6-eab950d6ea01

The open-access MAF lists 96 somatic variants for this specimen: 72 protein-altering or splice-affecting, 24 silent.
By variant classification: Missense Mutation 57, Silent 24, Nonsense Mutation 9, Frame Shift Ins 2, Splice Site 2, In Frame Del 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CEP250 | c.562C>T p.R188* | Nonsense Mutation (SNP) | VAF 9/52 reads (17%) | catalogued as rs1369076411, COSV100698749; ClinVar: pathogenic; called by muse, mutect2
- SLC26A4 | c.2162C>T p.T721M | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121908363, CM991031, COSV55920673; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AADAT | c.191G>A p.G64E | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT tolerated (0.87); PolyPhen benign (0.003); catalogued as COSV100528567; called by muse, mutect2, varscan2
- ACLY | c.1264C>T p.R422W | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1382363819, COSV61250418; called by muse, mutect2, varscan2
- ADGRB1 | c.1240G>A p.E414K | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.779); catalogued as COSV100029248; called by muse, mutect2
- ADGRG7 | c.997C>T p.Q333* | Nonsense Mutation (SNP) | VAF 10/92 reads (11%) | catalogued as COSV99840547, COSV99840589; called by muse, mutect2
- ANO3 | c.2665G>A p.D889N | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99880702; called by muse, mutect2, varscan2
- AP2A1 | c.1375G>T p.E459* | Nonsense Mutation (SNP) | VAF 6/78 reads (8%) | catalogued as COSV100756130; called by muse, mutect2
- ATP6V1G3 | c.146T>G p.M49R | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.773); catalogued as COSV99810696; called by muse, mutect2, varscan2
- BANK1 | c.1709A>T p.E570V | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.431); catalogued as COSV100535891; called by muse, mutect2, varscan2
- BRSK2 | c.633+1G>T p.X211_splice | Splice Site (SNP) | VAF 15/155 reads (10%) | catalogued as COSV100372349; called by muse, mutect2, varscan2
- BRWD1 | c.2195G>A p.R732H | Missense Mutation (SNP) | VAF 10/91 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.045); catalogued as COSV100312848; called by muse, mutect2, varscan2
- C2orf78 | c.2327C>T p.S776F | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs778082282, COSV101280900, COSV101280904; called by muse, mutect2, varscan2
- C3 | c.2670del p.K891Sfs*13 | Frame Shift Del (DEL) | VAF 13/97 reads (13%) | catalogued as rs750770711, COSV99837243; called by mutect2, varscan2
- CAPN6 | c.1579G>A p.D527N | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as COSV100136699; called by muse, mutect2
- CELSR2 | c.3784C>T p.L1262F | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as rs752137488, COSV99603089; called by muse, mutect2, varscan2
- CLDN2 | c.293C>T p.S98F | Missense Mutation (SNP) | VAF 4/51 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100390059; called by muse, mutect2
- COPS3 | c.818C>T p.S273L | Missense Mutation (SNP) | VAF 10/89 reads (11%) | SIFT tolerated (0.24); PolyPhen benign (0.015); catalogued as COSV99253471; called by muse, mutect2, varscan2
- CST4 | c.389G>A p.R130K | Missense Mutation (SNP) | VAF 13/113 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1419553328, COSV54149611, COSV54150215; called by muse, mutect2, varscan2
- CXorf21 | c.451G>T p.E151* | Nonsense Mutation (SNP) | VAF 5/38 reads (13%) | catalogued as COSV100973215; called by muse, mutect2, varscan2
- CYP7B1 | c.314dup p.N105Kfs*3 | Frame Shift Ins (INS) | VAF 19/132 reads (14%) | catalogued as rs747514385; called by mutect2, pindel, varscan2
- DEPDC5 | c.319C>T p.Q107* | Nonsense Mutation (SNP) | VAF 21/178 reads (12%) | catalogued as COSV56698334; called by muse, mutect2
- FAT4 | c.14324C>T p.P4775L | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.995); catalogued as rs537864241, COSV58703529; called by muse, mutect2, varscan2
- FZD1 | c.1560G>A p.M520I | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT tolerated (0.68); PolyPhen benign (0.074); catalogued as COSV99842373; called by muse, mutect2, varscan2
- GIMAP4 | c.595G>A p.E199K | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.9); catalogued as COSV99750440; called by muse, mutect2, varscan2
- GOLGA2 | c.1147A>T p.K383* | Nonsense Mutation (SNP) | VAF 14/85 reads (16%) | catalogued as COSV101363064; called by muse, mutect2, varscan2
- HIVEP1 | c.478G>A p.D160N | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as rs1189944839, COSV101044732; called by muse, mutect2, varscan2
- HSPG2 | c.4817C>T p.T1606M | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs183329264; called by muse, mutect2, varscan2
- IGHA2 | c.238G>A p.G80S | Missense Mutation (SNP) | VAF 45/91 reads (49%) | SIFT tolerated (0.26); PolyPhen benign (0.014); catalogued as rs782257693; called by muse, mutect2, varscan2
- IL23R | c.1585A>G p.N529D | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT tolerated (0.65); PolyPhen benign (0.003); catalogued as rs767996100, COSV100724595; called by muse, mutect2, varscan2
- KDM3A | c.1109C>T p.S370L | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.057); catalogued as COSV100460024; called by muse, mutect2
- KIF4A | c.3043G>A p.D1015N | Missense Mutation (SNP) | VAF 7/136 reads (5%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.997); catalogued as COSV100979386; called by muse, mutect2
- KPNA2 | c.853C>T p.R285* | Nonsense Mutation (SNP) | VAF 10/96 reads (10%) | catalogued as rs1266467492, COSV57857239; called by muse, mutect2
- MCCC1 | c.732G>A p.M244I | Missense Mutation (SNP) | VAF 9/146 reads (6%) | SIFT tolerated (0.05); PolyPhen benign (0.093); catalogued as COSV99659385; called by muse, mutect2
- METAP1 | c.494A>G p.E165G | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV99595381; called by muse, mutect2, varscan2
- METTL14 | c.19G>C p.E7Q | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT tolerated, low confidence (0.22); PolyPhen probably damaging (0.932); catalogued as COSV101183357, COSV66310934; called by muse, mutect2
- MME | c.1468G>A p.D490N | Missense Mutation (SNP) | VAF 20/147 reads (14%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV100852257, COSV100852515; called by muse, mutect2, varscan2
- MOGAT1 | c.10G>A p.E4K | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.04); catalogued as COSV101490087; called by muse, mutect2, varscan2
- MTMR2 | c.431G>A p.R144Q | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.066); catalogued as rs1555065007, COSV100656567; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NAALADL2 | c.377T>A p.L126* | Nonsense Mutation (SNP) | VAF 16/82 reads (20%) | catalogued as COSV101435746; called by muse, mutect2, varscan2
- NOL3 | c.418G>A p.E140K | Missense Mutation (SNP) | VAF 15/129 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.516); catalogued as COSV99220386; called by muse, mutect2, varscan2
- NOL4 | c.229G>A p.A77T | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT tolerated (0.5); PolyPhen benign (0.03); catalogued as COSV99305151; called by muse, mutect2, varscan2
- OR5M11 | c.421A>G p.I141V | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT tolerated (0.32); PolyPhen benign (0.021); catalogued as rs1301903798, COSV101602019, COSV73141667; called by muse, mutect2, varscan2
- PDE10A | c.191C>T p.S64L | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs754116544, COSV100604488; called by muse, mutect2, varscan2
- PLCH1 | c.4048C>G p.L1350V (on ENST00000340059 / NM_001130960.2; = p.L1342V on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/98 reads (11%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); catalogued as COSV100395634, COSV58187544; called by muse, mutect2, varscan2
- PRR19 | c.62G>A p.R21H | Missense Mutation (SNP) | VAF 21/166 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.104); catalogued as rs199545648, COSV100003640; called by muse, mutect2, varscan2
- RB1CC1 | c.1750T>C p.F584L | Missense Mutation (SNP) | VAF 64/364 reads (18%) | SIFT tolerated (0.42); PolyPhen benign (0.182); catalogued as rs776022372, COSV99206326; called by muse, varscan2
- RIOK3 | c.824A>C p.D275A | Missense Mutation (SNP) | VAF 7/140 reads (5%) | SIFT deleterious (0.05); PolyPhen benign (0.012); catalogued as COSV100259161; called by muse, mutect2
- RNF213 | c.6863A>G p.D2288G | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100299755; called by muse, mutect2, varscan2
- SLC2A2 | c.482C>T p.S161L | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.017); catalogued as COSV100049113; called by muse, mutect2, varscan2
- SLC44A4 | c.839A>G p.Y280C | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.365); catalogued as COSV99998620; called by muse, mutect2, varscan2
- SLITRK5 | c.562C>T p.L188F | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100280324, COSV61525386; called by muse, varscan2
- SPIDR | c.2176C>G p.L726V | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.274); catalogued as COSV99854286; called by muse, mutect2, varscan2
- TCEAL6 | c.151G>A p.E51K | Missense Mutation (SNP) | VAF 7/104 reads (7%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs1190696919, COSV101035907; called by muse, mutect2
- TDRD1 | c.385-1G>A p.X129_splice | Splice Site (SNP) | VAF 12/124 reads (10%) | catalogued as rs746542884, COSV99314092; called by muse, mutect2
- TENM1 | c.5729G>T p.C1910F | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.013); catalogued as COSV100949100; called by muse, mutect2, varscan2
- TIMP4 | c.523G>A p.E175K | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.581); catalogued as rs762591933, COSV55140420; called by muse, mutect2, varscan2
- TMPRSS7 | c.1145C>T p.S382L (on ENST00000452346; = p.S256L on NM_001042575.2) | Missense Mutation (SNP) | VAF 12/126 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV101340085; called by muse, mutect2, varscan2
- TNN | c.2690C>T p.T897M | Missense Mutation (SNP) | VAF 12/103 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs756201027, COSV99511134; called by muse, mutect2, varscan2
- TRO | c.1114C>G p.Q372E | Missense Mutation (SNP) | VAF 10/116 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as COSV99435810; called by muse, mutect2
- USP26 | c.881G>A p.C294Y | Missense Mutation (SNP) | VAF 25/245 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.326); catalogued as COSV63709819; called by muse, mutect2, varscan2
- USP5 | c.664C>T p.R222C | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.882); catalogued as COSV57536561; called by muse, mutect2, varscan2
- VPS13A | c.9515C>T p.P3172L | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs75740713; called by mutect2, varscan2
- WDHD1 | c.2728C>T p.R910* | Nonsense Mutation (SNP) | VAF 26/155 reads (17%) | catalogued as rs778414691, COSV62216053; called by muse, mutect2, varscan2
- WDPCP | c.1933G>A p.D645N | Missense Mutation (SNP) | VAF 11/112 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV99704069; called by muse, mutect2, varscan2
- XIAP | c.1069G>A p.E357K | Missense Mutation (SNP) | VAF 18/382 reads (5%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV100848820; called by muse, mutect2
- ZFHX3 | c.3341G>A p.R1114Q | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.127); catalogued as rs187631913, COSV51726666, COSV99195301; called by mutect2, varscan2
- ZNF41 | c.2032C>A p.L678I | Missense Mutation (SNP) | VAF 6/63 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV57444042; called by muse, mutect2, varscan2
- DMKN | c.1015G>A p.G339R | Missense Mutation (SNP) | VAF 23/214 reads (11%) | SIFT tolerated (0.64); PolyPhen benign (0.381); called by muse, mutect2, varscan2
- NLRP6 | c.1035_1052del p.E345_S350del | In Frame Del (DEL) | VAF 4/42 reads (10%) | called by mutect2, pindel
- SLC7A8 | c.1488dup p.E497Rfs*12 | Frame Shift Ins (INS) | VAF 3/35 reads (9%) | called by mutect2*, pindel
- SPATA31D1 | c.726G>C p.Q242H | Missense Mutation (SNP) | VAF 8/154 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0.02); called by muse, mutect2
- ABCA7 | c.4647C>T p.V1549= | Silent (SNP) | VAF 7/57 reads (12%) | catalogued as COSV99565179; called by muse, mutect2, varscan2
- C9orf135 | c.465G>A p.T155= | Silent (SNP) | VAF 13/88 reads (15%) | catalogued as rs750514307, COSV65874517; called by muse, mutect2, varscan2
- CENPF | c.6390C>T p.A2130= | Silent (SNP) | VAF 9/37 reads (24%) | catalogued as rs200126499, COSV65274429; called by muse, mutect2, varscan2
- CTRC | c.12C>T p.I4= | Silent (SNP) | VAF 6/42 reads (14%) | catalogued as rs1455830684, COSV101036282; called by muse, mutect2, varscan2
- DHX37 | c.270G>A p.K90= | Silent (SNP) | VAF 5/39 reads (13%) | catalogued as rs767327742, COSV100438974; called by muse, mutect2, varscan2
- EIF2AK1 | c.291G>A p.T97= | Silent (SNP) | VAF 15/140 reads (11%) | catalogued as rs780095730, COSV99551527; called by muse, mutect2, varscan2
- FBLN2 | c.1650C>T p.L550= | Silent (SNP) | VAF 8/40 reads (20%) | catalogued as COSV99851424; called by muse, mutect2, varscan2
- GIT1 | c.1266G>A p.T422= | Silent (SNP) | VAF 8/42 reads (19%) | catalogued as rs1269542316, COSV99837895; called by muse, mutect2, varscan2
- KRTAP10-7 | c.438C>T p.C146= | Silent (SNP) | VAF 6/93 reads (6%) | catalogued as rs587747240, COSV100170005; called by muse, mutect2
- LIG4 | c.1776G>A p.E592= | Silent (SNP) | VAF 13/48 reads (27%) | catalogued as COSV100799707; called by muse, mutect2, varscan2
- MBNL3 | c.45G>A p.L15= | Silent (SNP) | VAF 6/123 reads (5%) | catalogued as COSV100898440; called by muse, mutect2
- MCF2L2 | c.3174G>A p.R1058= | Silent (SNP) | VAF 18/88 reads (20%) | catalogued as rs773911610, COSV100191342; called by muse, mutect2, varscan2
- MID1 | c.1989A>C p.T663= | Silent (SNP) | VAF 6/48 reads (13%) | catalogued as COSV100452231; called by mutect2, varscan2
- OAZ2 | c.399C>T p.N133= | Silent (SNP) | VAF 6/30 reads (20%) | catalogued as COSV100386366, COSV58106486; called by muse, mutect2, varscan2
- PAQR9 | c.735C>T p.F245= | Silent (SNP) | VAF 9/66 reads (14%) | catalogued as rs754139353, COSV61417900; called by muse, mutect2, varscan2
- PRKCA | c.1194G>A p.P398= | Silent (SNP) | VAF 7/69 reads (10%) | catalogued as rs761333063, COSV52582472; called by muse, mutect2, varscan2
- REL | c.732C>T p.F244= | Silent (SNP) | VAF 8/48 reads (17%) | catalogued as rs753998705, COSV54368547, COSV99691846; called by muse, mutect2, varscan2
- SCARF1 | c.2214G>A p.R738= | Silent (SNP) | VAF 8/69 reads (12%) | catalogued as COSV53958616; called by muse, mutect2, varscan2
- SEPTIN4 | c.1386G>A p.R462= | Silent (SNP) | VAF 8/81 reads (10%) | catalogued as COSV100050778; called by mutect2, varscan2
- SGMS2 | c.717C>T p.F239= | Silent (SNP) | VAF 8/64 reads (13%) | catalogued as COSV100763429; called by muse, mutect2
- SLC23A2 | c.1407G>C p.L469= | Silent (SNP) | VAF 6/61 reads (10%) | catalogued as COSV100594785; called by muse, mutect2, varscan2
- VIRMA | c.294C>T p.I98= | Silent (SNP) | VAF 7/70 reads (10%) | catalogued as COSV99887630; called by muse, mutect2, varscan2
- WNK3 | c.363C>T p.F121= | Silent (SNP) | VAF 10/82 reads (12%) | catalogued as COSV100670804; called by muse, mutect2, varscan2
- ZMYM3 | c.1293C>G p.L431= | Silent (SNP) | VAF 6/48 reads (13%) | catalogued as COSV100077461; called by muse, mutect2, varscan2
